Somatic mutation profile of tumor specimen TCGA-HT-7694-01A (aliquot TCGA-HT-7694-01A-11D-2253-08) from TCGA case TCGA-HT-7694, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 60.0 years (21,930 days).
Specimen TCGA-HT-7694-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6c30639-d90d-4898-b80a-00ac8e989380.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7694-10A (Blood Derived Normal), aliquot TCGA-HT-7694-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e909472-3f0d-442e-b51e-6669e5c77cc3

The open-access MAF lists 36 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 8, Frame Shift Del 7, In Frame Del 3, 3'Flank 1, Intron 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 32/137 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRL4 | c.1508C>G p.A503G | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66060732; called by muse, mutect2, varscan2
- APOB | c.9397C>T p.P3133S | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51924392; called by muse, mutect2, varscan2
- CFH | c.1787_1789del p.S596del | In Frame Del (DEL) | VAF 25/110 reads (23%) | catalogued as rs1267853050; called by mutect2, pindel, varscan2
- CLIP2 | c.2474_2475del p.V825Gfs*36 | Frame Shift Del (DEL) | VAF 49/236 reads (21%) | catalogued as rs1323523835; called by pindel, varscan2
- COQ3 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as COSV54639560; called by muse, mutect2, varscan2
- FAM217B | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as COSV62564072; called by muse, mutect2, varscan2
- FUCA2 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771445547, COSV50019900; called by muse, mutect2, varscan2
- GLUD1 | c.563T>G p.I188S | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53277955; called by muse, mutect2, varscan2
- GNRHR | c.872G>A p.W291* | Nonsense Mutation (SNP) | VAF 21/344 reads (6%) | catalogued as COSV56933179; called by muse, mutect2
- H3-5 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as rs1018998701, COSV61186971; called by muse, mutect2, varscan2
- HAUS4 | c.713T>G p.L238R | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761723236, COSV52826973; called by muse, mutect2, varscan2
- MINAR1 | c.131C>A p.A44D | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV59581693; called by muse, mutect2, varscan2
- OLFML2A | c.1798T>C p.Y600H | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56582571; called by muse, mutect2, varscan2
- RBBP8 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV59091467; called by muse, mutect2, varscan2
- RNF144A | c.523A>G p.M175V | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV57981418; called by muse, mutect2, varscan2
- AGO1 | c.753_754del p.Q252Afs*29 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | called by pindel, varscan2
- ANKRD17 | c.4991_4992del p.R1664Kfs*17 | Frame Shift Del (DEL) | VAF 30/188 reads (16%) | called by pindel, varscan2
- CIC | c.1250dup p.L418Afs*15 | Frame Shift Ins (INS) | VAF 12/52 reads (23%) | called by mutect2, pindel
- DST | c.6148_6150del p.L2050del | In Frame Del (DEL) | VAF 47/187 reads (25%) | called by mutect2, pindel, varscan2
- FUBP1 | c.1631_1632del p.Y544Lfs*22 | Frame Shift Del (DEL) | VAF 31/110 reads (28%) | called by mutect2, pindel, varscan2
- OTUB1 | c.482_484del p.S161del | In Frame Del (DEL) | VAF 38/251 reads (15%) | called by pindel, varscan2
- PIK3R1 | c.49_53del p.E17Rfs*5 | Frame Shift Del (DEL) | VAF 16/182 reads (9%) | called by mutect2, pindel
- PTCD3 | c.1106_1109del p.L369Qfs*17 | Frame Shift Del (DEL) | VAF 25/184 reads (14%) | called by mutect2, pindel, varscan2
- SIN3A | c.2924_2943del p.D975Vfs*33 | Frame Shift Del (DEL) | VAF 24/218 reads (11%) | called by mutect2, pindel
- NBAS | c.3333A>G p.T1111= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as COSV55716475; called by mutect2, varscan2
- NCOR1 | c.3522G>A p.Q1174= | Silent (SNP) | VAF 6/149 reads (4%) | catalogued as COSV51959551, COSV51968112; called by muse, mutect2
- PDP2 | c.1218C>T p.F406= | Silent (SNP) | VAF 43/145 reads (30%) | catalogued as rs1334809558, COSV61240254, COSV61240325; called by muse, mutect2, varscan2
- RFT1 | c.1380G>A p.R460= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV56248465; called by muse, mutect2, varscan2
- SLC35A1 | c.123C>G p.L41= | Silent (SNP) | VAF 9/149 reads (6%) | catalogued as COSV65779910; called by muse, mutect2
- TREML2 | c.225C>T p.P75= | Silent (SNP) | VAF 13/228 reads (6%) | catalogued as COSV72439067; called by muse, mutect2
- TSC22D4 | c.1098C>A p.R366= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV55723704, COSV55724269; called by muse, mutect2
- VDAC2 | c.474G>A p.E158= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV53685473; called by muse, mutect2, varscan2
- C3orf35 | chr3:37417447 A>G | 3'Flank (SNP) | VAF 28/119 reads (24%) | called by muse, mutect2, varscan2
- MBNL1 | c.174+40418A>G | Intron (SNP) | VAF 27/120 reads (23%) | catalogued as COSV56825781; called by muse, mutect2, varscan2
